Surgical pathology report (de-identified scan), TCGA case TCGA-D7-6519, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-6519-01A (Primary Tumor).

Examination: Histopathological examination

Material: Total organ resection – stomach

Physician in charge:

Material collected on: Material received on:

Expected time of examination:

Clinical diagnosis:

TCGA – D7 – 6519

Examination performed on:

Macroscopic description:

Sent material containing the stomach, incised along the greater curvature, sized 19.2 x 13.2 cm with the omentum sized 20 x 8 cm. Wall thickening in the orifice region over the area of 4.8 x 6.2 x 1.4 cm. Distance from the proximal end: 0.8cm, from distal end: 13.1 cm.

Microscopic description:

Adenocarcinoma mucocellulare ventriculi (typus mixtus s. Lauren; G3) - Infiltratio parietis totae ventriculi - pT2).

Incision lines free of neoplastic lesions. Invasio vasorum.

Metastases in lymphonodis (II / XVI).

Histopathological diagnosis:

(Including test No. G-15580/10):

Adenocarcinoma mucocellulare ventriculi. (Mucocellular adenocarcinoma of the stomach ,

Metastases in lymphonodis (II/ XVI), lymph nodes with metastases (II/XVI)

Invasio vasorum, vascular invasion

(G3,pT2, pN1).

Source: NCI Genomic Data Commons file a4cfa7cc-4e9b-4405-9df1-60d0db61ac87 (TCGA-D7-6519.821687F8-D2C1-46AB-BE51-1ADDEC01500B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).